Somatic mutation profile of tumor specimen TCGA-EM-A2OZ-01A (aliquot TCGA-EM-A2OZ-01A-11D-A202-08) from TCGA case TCGA-EM-A2OZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 66.2 years (24,195 days).
Specimen TCGA-EM-A2OZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3b605ed-4ee0-495c-a9bc-cbc526460b2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2OZ-10A (Blood Derived Normal), aliquot TCGA-EM-A2OZ-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cdfe0b6-20ac-4694-82b1-92d9dafc3560

The open-access MAF lists 23 somatic variants for this specimen: 11 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 11, Missense Mutation 8, In Frame Del 1, Splice Region 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA12 | c.6393G>A p.P2131= (on ENST00000272895 / NM_173076.3; = p.P1813= on NM_015657.3) | Splice Region (SNP) | VAF 16/47 reads (34%) | catalogued as rs200758693, COSV99788462; called by muse, mutect2, varscan2
- ABHD6 | c.620C>G p.P207R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as rs367601823, COSV55910761; called by mutect2, varscan2
- ARAP3 | c.3235G>C p.E1079Q | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV53355858; called by muse, mutect2
- BRCA1 | c.1554C>G p.I518M | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58790472; called by muse, mutect2
- COL15A1 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66650290; called by muse, mutect2, varscan2
- FNIP2 | c.1988C>G p.S663* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs970348921, COSV52447394; called by muse, mutect2
- STX1B | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as COSV53062144, COSV53062428; called by muse, mutect2
- UQCRC2 | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs202168192, COSV51674583; called by muse, mutect2, varscan2
- LYZL6 | c.206G>C p.S69T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PRDM16 | c.1873_1884del p.L625_D628del | In Frame Del (DEL) | VAF 32/101 reads (32%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.2835G>C p.L945= | Silent (SNP) | VAF 26/239 reads (11%) | catalogued as COSV60911548; called by muse, mutect2, varscan2
- DLG5 | c.1641G>C p.L547= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100967948, COSV64950422; called by muse, mutect2
- FRY | c.2325G>A p.G775= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as rs1284513530, COSV66582297; called by muse, mutect2
- FTO | c.1344G>A p.L448= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV51663222, COSV51669659; called by muse, mutect2, varscan2
- GPC1 | c.750C>G p.V250= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV50867514; called by muse, mutect2
- IL12A | c.708C>T p.F236= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV59758995, COSV59760382; called by muse, mutect2
- ITIH6 | c.2136T>C p.D712= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV54496028; called by muse, mutect2, varscan2
- MGMT | c.291G>A p.L97= (on ENST00000306010; = p.L66= on NM_002412.5) | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV60026206; called by muse, mutect2, varscan2
- MPV17 | c.258G>A p.L86= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV51992321; called by muse, mutect2, varscan2
- NPC1L1 | c.1746G>A p.G582= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV56931330; called by muse, mutect2
- SCG3 | c.852G>A p.L284= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV55023733; called by muse, mutect2
- CPLANE1 | c.*5166T>G | 3'UTR (SNP) | VAF 10/79 reads (13%) | catalogued as COSV57077343; called by muse, mutect2, varscan2
